Somatic mutation profile of tumor specimen TCGA-WB-A81K-01A (aliquot TCGA-WB-A81K-01A-11D-A35I-08) from TCGA case TCGA-WB-A81K, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 45.1 years (16,483 days).
Specimen TCGA-WB-A81K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70888a87-3028-45da-9362-975c886bcb58.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A81K-10A (Blood Derived Normal), aliquot TCGA-WB-A81K-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c08ad39-9c09-467f-b17a-ed995075afa3

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAT4 | c.12923C>G p.T4308S | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV58705003; called by muse, mutect2
- ECD | c.1199T>A p.L400H | Missense Mutation (SNP) | VAF 21/287 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- FBXO8 | c.265A>G p.T89A | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NSUN2 | c.2071C>A p.P691T | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.206); called by muse, mutect2
- SLC36A2 | c.400A>T p.N134Y | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- PRTG | c.1569T>C p.I523= | Silent (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
